Somatic mutation profile of tumor specimen TARGET-10-PARPZR-09A (aliquot TARGET-10-PARPZR-09A-01D) from TARGET case TARGET-10-PARPZR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (490 days).
Specimen TARGET-10-PARPZR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c92471a-592f-497d-bc39-1fa3d960d59e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPZR-10A (Blood Derived Normal), aliquot TARGET-10-PARPZR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e33d9edf-babc-42d3-bd20-5a1efa36a75d

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.3848C>T p.T1283M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs546817149; called by muse, mutect2
- CD47 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.185); catalogued as rs1176172930; called by muse, mutect2, varscan2
- SYNM | c.4478C>T p.A1493V (on ENST00000336292 / NM_145728.3; = p.A1181V on NM_015286.6) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs372660853; called by muse, mutect2, varscan2
- ZNF846 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CASP5 | c.831G>A p.A277= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs778906548, COSV52827618; called by muse, mutect2, varscan2
- MAGED1 | c.1683T>A p.G561= | Silent (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- USH2A | c.4869G>C p.L1623= | Silent (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2431+114G>A | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as rs1054180814; called by muse, mutect2, varscan2
